Gene-level copy-number profile of tumor specimen TCGA-TS-A8AF-01A from TCGA case TCGA-TS-A8AF, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 69.8 years (25,486 days).
Specimen TCGA-TS-A8AF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.d47a832e-e0bb-4136-aa12-aafb2c7cb230.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TS-A8AF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/343185fb-cbdf-44f0-a4d3-d0dfa07ede55

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 2: 917; copy number 3: 8,589; copy number 4: 8,289; copy number 5: 21,521; copy number 6: 10,996; copy number 7: 7,933; copy number 8: 743; copy number 9: 80; copy number 10: 528; copy number 11: 5; copy number 12: 116.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,789,179–24,905,735, 89 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 121 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,711,277–34,165,842, 116 genes, copy number 12 (within-gene range 10–12) (broad region; genes not listed).
- chr1:121,494,329–121,580,524, 5 genes, copy number 11: AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
